Somatic mutation profile of tumor specimen 0DIAC3 from CCDI case PBBVNT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.5 years (2,372 days).
Specimen 0DIAC3: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c008c9e-2bd0-490f-ab0c-0d5204d20a66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIACE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f72c6bb4-9b0b-4dcc-996b-6e8fba410d5b

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 3, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP39 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.608); catalogued as rs868436060, COSV52770419; called by muse, mutect2
- C10orf90 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 36/560 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.001); catalogued as COSV52958204; called by muse, mutect2
- CATSPER4 | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 56/760 reads (7%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.493); catalogued as rs148720324; called by muse, mutect2
- COL12A1 | c.3160C>T p.R1054* | Nonsense Mutation (SNP) | VAF 19/456 reads (4%) | catalogued as rs868543538, COSV59398601; called by muse, mutect2
- DCHS1 | c.9217G>T p.A3073S | Missense Mutation (SNP) | VAF 94/438 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.113); catalogued as rs1023747102; called by muse, mutect2, varscan2
- ITIH1 | c.2506C>T p.H836Y | Missense Mutation (SNP) | VAF 60/676 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs777431003; called by muse, mutect2
- LRRC4B | c.1033G>T p.G345C | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.629); catalogued as COSV65350753; called by muse, mutect2
- OBI1 | c.1817A>G p.E606G | Missense Mutation (SNP) | VAF 183/456 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as rs149986119; called by muse, mutect2, varscan2
- PAPSS2 | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 17/519 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1197252611, COSV63263660; called by muse, mutect2
- SEC14L3 | c.328G>T p.G110W | Missense Mutation (SNP) | VAF 20/594 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs940261793; called by muse, mutect2
- ARHGAP26 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 37/399 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CCDC168 | c.20300A>G p.D6767G | Missense Mutation (SNP) | VAF 40/248 reads (16%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- DCDC1 | c.2948A>T p.E983V (on ENST00000597505 / NM_001367979.1; = p.E90V on NM_020869.3) | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); called by muse, varscan2
- FAM205A | c.1512T>A p.H504Q | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.043); called by mutect2, varscan2
- GDI2 | c.1189C>G p.Q397E | Missense Mutation (SNP) | VAF 54/348 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- HERC5 | c.3018G>C p.M1006I | Missense Mutation (SNP) | VAF 63/456 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.127); called by muse, varscan2
- PIGT | c.1115T>G p.L372R | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- PTK6 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 84/442 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RHOBTB3 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 77/525 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- TBC1D25 | c.1693C>G p.P565A | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2
- TTN | c.93079G>C p.G31027R (on ENST00000591111; = p.G23603R on NM_003319.4) | Missense Mutation (SNP) | VAF 97/509 reads (19%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL22A1 | c.2160T>A p.G720= | Silent (SNP) | VAF 57/576 reads (10%) | called by muse, mutect2
- RGS11 | c.1368G>A p.A456= (on ENST00000397770 / NM_183337.3; = p.A435= on NM_003834.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 128/332 reads (39%) | catalogued as rs767291709, COSV51452531; called by muse, mutect2, varscan2
- SLC8A3 | c.1692C>A p.V564= | Silent (SNP) | VAF 55/201 reads (27%) | catalogued as COSV100776433; called by muse, mutect2, varscan2
- C9orf72 | c.*72C>T | 3'UTR (SNP) | VAF 4/45 reads (9%) | catalogued as rs1429081629, COSV101187051; called by muse, varscan2
- CIAO3 | c.306+65G>A | Intron (SNP) | VAF 16/116 reads (14%) | catalogued as rs774842000; called by muse, varscan2
- RBL2 | c.2245+48T>A | Intron (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
